Somatic mutation profile of tumor specimen TCGA-CH-5768-01A (aliquot TCGA-CH-5768-01A-11D-1576-08) from TCGA case TCGA-CH-5768, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 72.5 years (26,480 days).
Specimen TCGA-CH-5768-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b2e5dba5-b04b-4838-8c0d-b3f631b7f70c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CH-5768-11A (Solid Tissue Normal), aliquot TCGA-CH-5768-11A-01D-1576-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6958644f-ee20-41d4-9b2f-5255c4947345

The open-access MAF lists 47 somatic variants for this specimen: 35 protein-altering or splice-affecting, 11 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 11, Nonsense Mutation 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MTOR | c.5930C>G p.T1977R | Missense Mutation (SNP) | VAF 15/192 reads (8%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV63868784, COSV63869673, COSV63869920; called by muse, mutect2
- PROCR | c.293G>T p.R98L | Missense Mutation (SNP) | VAF 5/16 reads (31%) | hotspot (GDC flag); SIFT tolerated (0.59); PolyPhen benign (0.133); catalogued as rs200377875, COSV53825026, COSV53826359; called by muse, mutect2
- AC013489.1 | c.568G>C p.D190H | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.329); catalogued as COSV51552966; called by muse, mutect2, varscan2
- AP4B1 | c.826C>T p.R276W | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs758248128, COSV56724446; called by muse, mutect2, varscan2
- APOB | c.10673G>A p.R3558H | Missense Mutation (SNP) | VAF 59/170 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.062); catalogued as rs762035088, COSV51930542; called by muse, varscan2
- B3GAT3 | c.21C>A p.N7K | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.028); catalogued as rs779934549, COSV55490135; called by muse, mutect2, varscan2
- BTNL3 | c.896C>T p.P299L | Missense Mutation (SNP) | VAF 54/213 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs200172568, COSV61565484; called by muse, mutect2, varscan2
- CDPF1 | c.182G>A p.G61D | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53080722; called by muse, mutect2
- DGKI | c.2960T>A p.L987* | Nonsense Mutation (SNP) | VAF 8/203 reads (4%) | catalogued as COSV55968411; called by muse, mutect2
- DNAH3 | c.5695C>T p.R1899C | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs146618931, COSV54542505; called by muse, mutect2, varscan2
- FRY | c.3271C>T p.R1091W | Missense Mutation (SNP) | VAF 14/225 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV66575607; called by muse, mutect2
- GALNT17 | c.1094G>A p.G365E | Missense Mutation (SNP) | VAF 18/258 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100352538, COSV61182193; called by muse, mutect2
- GRIN2A | c.3120G>T p.E1040D | Missense Mutation (SNP) | VAF 108/368 reads (29%) | SIFT tolerated (0.52); PolyPhen benign (0.171); catalogued as COSV58050942; called by muse, mutect2, varscan2
- IGHM | c.521C>T p.T174M | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.895); catalogued as rs540744199; called by muse, mutect2, varscan2
- KLK3 | c.306T>G p.D102E | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV58102175; called by muse, mutect2, varscan2
- LCE2D | c.254G>A p.R85Q | Missense Mutation (SNP) | VAF 46/108 reads (43%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.037); catalogued as rs113433987; called by mutect2, varscan2
- LRP1 | c.7721G>A p.S2574N | Missense Mutation (SNP) | VAF 3/56 reads (5%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV54521180; called by muse, mutect2
- MYO15A | c.6784C>T p.R2262C | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs779584672, COSV52762504; called by muse, varscan2
- PCSK2 | c.1616G>A p.R539H | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52732700; called by muse, mutect2, varscan2
- PDZD2 | c.4067G>A p.G1356D | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as COSV56868687; called by muse, mutect2, varscan2
- PSRC1 | c.337C>T p.R113W | Missense Mutation (SNP) | VAF 48/105 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767431636, COSV64021576; called by muse, mutect2, varscan2
- RYR2 | c.14235C>A p.D4745E | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV63705271; called by muse, mutect2, varscan2
- SEL1L3 | c.2345A>G p.K782R | Missense Mutation (SNP) | VAF 57/170 reads (34%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.517); catalogued as COSV53547305; called by muse, mutect2, varscan2
- SLC27A6 | c.1358T>A p.F453Y | Missense Mutation (SNP) | VAF 98/326 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52486345; called by muse, mutect2, varscan2
- SMARCA1 | c.2829C>A p.Y943* | Nonsense Mutation (SNP) | VAF 71/92 reads (77%) | catalogued as COSV64413303; called by muse, mutect2, varscan2
- SPHKAP | c.319G>A p.V107I | Missense Mutation (SNP) | VAF 30/194 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.992); catalogued as rs531679897, COSV60890406; called by muse, mutect2, varscan2
- SULF1 | c.1466C>T p.T489M | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.18); catalogued as rs754254845, COSV52684786; called by muse, mutect2, varscan2
- TEX11 | c.1666A>G p.I556V (on ENST00000344304; = p.I541V on NM_031276.3) | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV60236559; called by muse, mutect2
- TNXB | c.3584C>T p.T1195M (on ENST00000647633; = p.T948M on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.961); catalogued as rs950928412, COSV64475862; called by muse, mutect2
- TTN | c.40166A>C p.E13389A (on ENST00000591111; = p.E5965A on NM_003319.4) | Missense Mutation (SNP) | VAF 9/76 reads (12%) | PolyPhen probably damaging (0.995); catalogued as rs747875588, COSV60258563; called by muse, mutect2, varscan2
- TXN2 | c.115C>T p.P39S | Missense Mutation (SNP) | VAF 38/132 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV53398133; called by muse, mutect2, varscan2
- WDR77 | c.934C>G p.L312V | Missense Mutation (SNP) | VAF 17/160 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.052); catalogued as COSV52386019; called by muse, mutect2
- ZNF276 | c.1798C>T p.P600S (on ENST00000443381 / NM_001113525.2; = p.P525S on NM_152287.4) | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.027); catalogued as rs1257278189, COSV57071498; called by muse, mutect2
- ZSCAN26 | c.577A>G p.T193A (on ENST00000623276 / NM_001111039.2; = p.T59A on NM_152736.5) | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT tolerated (0.47); PolyPhen benign (0.108); catalogued as COSV57271930; called by muse, mutect2
- NCOA4 | c.932C>T p.S311F | Missense Mutation (SNP) | VAF 49/152 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0.361); called by muse, mutect2, varscan2
- ADAM12 | c.1869C>T p.G623= | Silent (SNP) | VAF 148/436 reads (34%) | catalogued as rs539968083, COSV64104555; called by muse, mutect2, varscan2
- AXDND1 | c.2067C>T p.N689= | Silent (SNP) | VAF 40/192 reads (21%) | catalogued as rs141202947; called by muse, mutect2, varscan2
- CCDC178 | c.2595C>T p.N865= (on ENST00000383096 / NM_001105528.3; = p.N827= on NM_198995.3) | Silent (SNP) | VAF 38/108 reads (35%) | catalogued as rs959855208, COSV55790414; called by muse, mutect2, varscan2
- COL3A1 | c.3882T>C p.C1294= | Silent (SNP) | VAF 52/193 reads (27%) | catalogued as rs1033051824, COSV58594463; called by muse, mutect2, varscan2
- GAD2 | c.1395C>T p.T465= | Silent (SNP) | VAF 35/126 reads (28%) | catalogued as rs753339116, COSV52165019, COSV99393726; called by muse, mutect2, varscan2
- NCOR1 | c.3696T>G p.T1232= | Silent (SNP) | VAF 10/154 reads (6%) | catalogued as COSV51989487; called by muse, mutect2
- PCARE | c.1647C>T p.S549= | Silent (SNP) | VAF 50/156 reads (32%) | catalogued as rs779448335, COSV59056895; called by muse, mutect2, varscan2
- POLE | c.1371G>A p.T457= | Silent (SNP) | VAF 49/136 reads (36%) | catalogued as rs753216372, COSV57687238; ClinVar: likely benign; called by muse, mutect2, varscan2
- PRSS22 | c.801C>T p.A267= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as COSV50722012; called by mutect2, varscan2
- RBFOX1 | c.489C>T p.F163= | Silent (SNP) | VAF 93/238 reads (39%) | catalogued as rs1386916670, COSV60948645; called by muse, mutect2, varscan2
- SLC45A4 | c.1782C>T p.Y594= (on ENST00000517878 / NM_001286646.2; = p.Y543= on NM_001080431.2) | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as rs751693756, COSV50160859; called by muse, mutect2, varscan2
- ABCC6 | c.*2C>T | 3'UTR (SNP) | VAF 8/50 reads (16%) | catalogued as COSV99228621; called by muse, varscan2
